Somatic mutation profile of tumor specimen C3L-01682-01 (aliquot CPT0110860010) from CPTAC case C3L-01682, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 78.5 years (28,669 days).
Specimen C3L-01682-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1a1a710f-ee57-4552-b426-9d0980c049ad.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01682-31 (Blood Derived Normal), aliquot CPT0112370002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/27349a85-f265-4ba0-a8db-753473235257

The open-access MAF lists 133 somatic variants for this specimen: 93 protein-altering or splice-affecting, 27 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 81, Silent 27, Nonsense Mutation 6, Intron 4, Frame Shift Del 3, 3'Flank 3, 5'Flank 3, RNA 2, 3'UTR 1, Frame Shift Ins 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.517G>T p.V173L | Missense Mutation (SNP) | VAF 67/415 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs876660754, CM070299, COSV52676535, COSV52677795, COSV52695723, COSV52823354; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- B3GAT2 | c.299G>C p.R100P | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755698058; called by muse, mutect2, varscan2
- CARTPT | c.329C>A p.S110Y | Missense Mutation (SNP) | VAF 46/455 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.067); catalogued as rs1302611855, COSV57114797; called by muse, mutect2, varscan2
- CCT8L2 | c.587G>C p.G196A | Missense Mutation (SNP) | VAF 11/194 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.574); catalogued as rs1171016270, COSV100743157; called by muse, mutect2
- CTNND2 | c.3187C>T p.R1063C | Missense Mutation (SNP) | VAF 18/456 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as rs1561136061, COSV58892661; called by muse, mutect2
- DOK2 | c.53C>T p.T18M | Missense Mutation (SNP) | VAF 20/324 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as rs775200531, COSV52389760; called by muse, mutect2
- FAM193A | c.1435A>G p.T479A | Missense Mutation (SNP) | VAF 8/184 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1411223618; called by muse, mutect2
- FCRL5 | c.2301C>A p.D767E | Missense Mutation (SNP) | VAF 23/206 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.447); catalogued as rs747628051; called by muse, mutect2, varscan2
- GPR62 | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 14/232 reads (6%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV59055207; called by muse, mutect2
- HMCN1 | c.9676G>T p.A3226S | Missense Mutation (SNP) | VAF 50/413 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1343012503; called by muse, mutect2, varscan2
- KCNH6 | c.995G>A p.S332N | Missense Mutation (SNP) | VAF 46/366 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs759222952; called by muse, mutect2, varscan2
- KDM4B | c.1559C>G p.A520G | Missense Mutation (SNP) | VAF 25/243 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.047); catalogued as COSV99346060; called by muse, mutect2, varscan2
- KRTAP1-4 | c.95C>A p.T32N | Missense Mutation (SNP) | VAF 74/536 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.14); catalogued as COSV60335626; called by muse, mutect2, varscan2
- LMNA | c.569G>T p.R190L | Missense Mutation (SNP) | VAF 59/542 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs267607571, CM050658, CM1414666, COSV61542038; called by mutect2, varscan2
- LRRC18 | c.406G>A p.V136M | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.502); catalogued as rs138127999; called by muse, mutect2, varscan2
- PELP1 | c.2218C>G p.L740V | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.34); catalogued as COSV52592656; called by muse, mutect2, varscan2
- PEX13 | c.80G>A p.G27D | Missense Mutation (SNP) | VAF 17/159 reads (11%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.495); catalogued as rs1431057080; called by muse, mutect2, varscan2
- PLXNB3 | c.9C>A p.H3Q | Missense Mutation (SNP) | VAF 15/300 reads (5%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.005); catalogued as rs1168379326; called by muse, mutect2
- RBM10 | c.838G>T p.G280* | Nonsense Mutation (SNP) | VAF 26/229 reads (11%) | catalogued as COSV61308782; called by muse, mutect2, varscan2
- RPGR | c.778+1G>T p.X260_splice | Splice Site (SNP) | VAF 32/439 reads (7%) | catalogued as CS067115; called by muse, mutect2
- SALL3 | c.3008G>T p.R1003L | Missense Mutation (SNP) | VAF 21/286 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.068); catalogued as COSV73305857; called by muse, mutect2
- SAMD4B | c.844G>C p.E282Q | Missense Mutation (SNP) | VAF 9/272 reads (3%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.968); catalogued as COSV58753249; called by muse, mutect2
- SHANK2 | c.5024C>T p.T1675M | Missense Mutation (SNP) | VAF 14/280 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs1372604596, COSV99573473; called by muse, mutect2
- SLC1A6 | c.1000G>T p.V334F | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as COSV55668860, COSV55674280; called by muse, mutect2, varscan2
- SLC45A1 | c.1694C>T p.A565V | Missense Mutation (SNP) | VAF 28/287 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.061); catalogued as rs748149515; called by muse, mutect2, varscan2
- SLITRK2 | c.1709A>C p.K570T | Missense Mutation (SNP) | VAF 20/170 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.145); catalogued as rs782276159; called by muse, mutect2, varscan2
- TDRD15 | c.4030C>G p.L1344V | Missense Mutation (SNP) | VAF 8/224 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.091); catalogued as rs995120642; called by muse, mutect2
- TENM1 | c.5860G>T p.G1954C | Missense Mutation (SNP) | VAF 46/237 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64445710; called by muse, mutect2, varscan2
- TNFRSF13C | c.226G>T p.G76W | Missense Mutation (SNP) | VAF 32/407 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); catalogued as rs1037657715; called by muse, mutect2
- TTN | c.64A>T p.T22S | Missense Mutation (SNP) | VAF 30/505 reads (6%) | PolyPhen benign (0.005); catalogued as COSV60234003; called by muse, mutect2
- ADAM19 | c.2641C>A p.P881T | Missense Mutation (SNP) | VAF 30/296 reads (10%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2
- ADAM19 | c.2024dup p.W676Lfs*23 | Frame Shift Ins (INS) | VAF 5/41 reads (12%) | called by mutect2, pindel, varscan2
- ANKRD44 | c.2519G>T p.R840M | Missense Mutation (SNP) | VAF 22/267 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ANKRD44 | c.2518A>T p.R840W | Missense Mutation (SNP) | VAF 24/273 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ATP2B3 | c.3218C>A p.P1073H | Missense Mutation (SNP) | VAF 11/198 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.011); called by muse, mutect2
- CBLN1 | c.454G>A p.A152T | Missense Mutation (SNP) | VAF 35/515 reads (7%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.992); called by muse, mutect2
- COL5A1 | c.971G>T p.S324I | Missense Mutation (SNP) | VAF 42/568 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.018); called by muse, mutect2
- COL5A1 | c.3808G>T p.G1270C | Missense Mutation (SNP) | VAF 32/470 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DCSTAMP | c.466A>G p.T156A | Missense Mutation (SNP) | VAF 14/286 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.005); called by muse, mutect2
- DNAH6 | c.876G>C p.K292N | Missense Mutation (SNP) | VAF 16/172 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2
- DRC1 | c.1743C>A p.S581R | Missense Mutation (SNP) | VAF 48/395 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- DTL | c.1670C>T p.S557L | Missense Mutation (SNP) | VAF 26/388 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.255); called by muse, mutect2
- EFNB2 | c.227A>G p.Y76C | Missense Mutation (SNP) | VAF 16/264 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- EHD1 | c.88G>T p.A30S | Missense Mutation (SNP) | VAF 10/212 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2
- FASN | c.5799G>T p.R1933S | Missense Mutation (SNP) | VAF 26/366 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); called by muse, mutect2
- FBN3 | c.5467G>A p.D1823N | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT tolerated (0.45); PolyPhen benign (0.306); called by muse, mutect2
- FBXL13 | c.626A>T p.D209V | Missense Mutation (SNP) | VAF 26/252 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- FCRL5 | c.2302C>A p.L768M | Missense Mutation (SNP) | VAF 24/207 reads (12%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- GPR174 | c.259G>A p.G87R | Missense Mutation (SNP) | VAF 17/245 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- GRIP2 | c.664C>A p.L222M (on ENST00000619221; = p.L125M on NM_001080423.4) | Missense Mutation (SNP) | VAF 20/190 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRM5 | c.2059T>A p.F687I | Missense Mutation (SNP) | VAF 30/370 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- GSDMA | c.1159G>T p.E387* | Nonsense Mutation (SNP) | VAF 42/478 reads (9%) | called by muse, mutect2
- HCFC1 | c.4087A>T p.T1363S | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- IBSP | c.631G>T p.A211S | Missense Mutation (SNP) | VAF 14/224 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0.014); called by muse, mutect2
- IBTK | c.518C>G p.S173C | Missense Mutation (SNP) | VAF 11/226 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.903); called by muse, mutect2
- KLB | c.907C>G p.H303D | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.642); called by muse, mutect2
- LAMA5 | c.10878C>G p.N3626K | Missense Mutation (SNP) | VAF 15/208 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.34); called by muse, mutect2
- LHCGR | c.2060G>T p.G687V | Missense Mutation (SNP) | VAF 29/273 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0.015); called by muse, varscan2
- LRP1B | c.7630C>A p.L2544M | Missense Mutation (SNP) | VAF 26/359 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.033); called by muse, mutect2
- LRP1B | c.2403T>A p.N801K | Missense Mutation (SNP) | VAF 16/270 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2
- MAGI2 | c.3030G>C p.E1010D | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT tolerated (0.75); PolyPhen benign (0.106); called by muse, mutect2
- MAP2 | c.5335A>T p.I1779F | Missense Mutation (SNP) | VAF 39/389 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- MCM8 | c.1598C>T p.A533V | Missense Mutation (SNP) | VAF 37/329 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- MED13L | c.2344+7A>G | Splice Region (SNP) | VAF 14/393 reads (4%) | called by muse, mutect2
- MYEOV | c.406G>T p.V136F | Missense Mutation (SNP) | VAF 20/563 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.635); called by muse, mutect2
- NFRKB | c.1910G>T p.C637F (on ENST00000446488 / NM_001143835.2; = p.C662F on NM_006165.3) | Missense Mutation (SNP) | VAF 14/372 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- NOC3L | c.1349del p.F450Sfs*22 | Frame Shift Del (DEL) | VAF 14/126 reads (11%) | called by mutect2, pindel, varscan2
- NUDT7 | c.98C>G p.S33C | Missense Mutation (SNP) | VAF 9/234 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- OR14A16 | c.710C>A p.S237Y | Missense Mutation (SNP) | VAF 17/195 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- OR14A16 | c.708C>A p.Y236* | Nonsense Mutation (SNP) | VAF 20/204 reads (10%) | called by muse, mutect2
- POP4 | c.247G>C p.E83Q | Missense Mutation (SNP) | VAF 14/266 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2
- PRRC2B | c.4496C>T p.A1499V | Missense Mutation (SNP) | VAF 11/211 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2
- PSG1 | c.242C>A p.S81* | Nonsense Mutation (SNP) | VAF 16/356 reads (4%) | called by muse, mutect2
- RAB33B | c.212G>A p.R71Q | Missense Mutation (SNP) | VAF 13/240 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.719); called by muse, mutect2
- RBM10 | c.837G>T p.Q279H | Missense Mutation (SNP) | VAF 26/232 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- RNF115 | c.101C>T p.P34L | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SAXO1 | c.779G>T p.R260M | Missense Mutation (SNP) | VAF 24/342 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.827); called by muse, mutect2
- SCRIB | c.1244T>A p.L415* | Nonsense Mutation (SNP) | VAF 11/230 reads (5%) | called by muse, mutect2
- SERPINB10 | c.1064G>T p.S355I | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.021); called by muse, mutect2
- SGCZ | c.302T>A p.L101H | Missense Mutation (SNP) | VAF 7/201 reads (3%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.824); called by muse, mutect2
- SHROOM2 | c.1330G>T p.G444W | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- SLC34A2 | c.1796_1809del p.S599* | Frame Shift Del (DEL) | VAF 8/88 reads (9%) | called by mutect2, pindel
- SLC8A3 | c.1205C>T p.P402L | Missense Mutation (SNP) | VAF 45/296 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SNX14 | c.1654G>T p.A552S (on ENST00000314673 / NM_001350535.1; = p.A499S on NM_020468.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/332 reads (10%) | SIFT tolerated (0.72); PolyPhen benign (0.114); called by muse, varscan2
- SPTA1 | c.4002C>G p.H1334Q | Missense Mutation (SNP) | VAF 15/346 reads (4%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.649); called by muse, mutect2
- TARS1 | c.1824_1831del p.Y608* | Frame Shift Del (DEL) | VAF 28/232 reads (12%) | called by mutect2, pindel
- TMEM74 | c.743G>A p.C248Y | Missense Mutation (SNP) | VAF 24/210 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- TNFRSF6B | c.427A>T p.T143S | Missense Mutation (SNP) | VAF 30/199 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- TREML4 | c.493G>T p.G165C | Missense Mutation (SNP) | VAF 17/184 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); called by muse, mutect2
- TRIM50 | c.1186G>T p.E396* | Nonsense Mutation (SNP) | VAF 10/177 reads (6%) | called by muse, mutect2
- TRPV2 | c.941T>A p.L314Q | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by mutect2, varscan2
- WDSUB1 | c.1079G>A p.G360E | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- YIPF3 | c.566G>C p.G189A | Missense Mutation (SNP) | VAF 11/302 reads (4%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.998); called by muse, mutect2
- ABCG8 | c.84C>T p.F28= | Silent (SNP) | VAF 44/442 reads (10%) | called by muse, mutect2, varscan2
- ANK3 | c.5778G>A p.E1926= | Silent (SNP) | VAF 40/354 reads (11%) | called by muse, mutect2, varscan2
- ANKFN1 | c.3429G>A p.P1143= (on ENST00000653862; = p.P996= on NM_001365758.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/309 reads (3%) | catalogued as rs1234071082; called by muse, mutect2
- B3GNTL1 | c.291A>G p.K97= | Silent (SNP) | VAF 21/280 reads (8%) | catalogued as rs766775389; called by muse, mutect2
- C10orf90 | c.942A>G p.P314= | Silent (SNP) | VAF 16/463 reads (3%) | called by muse, mutect2
- CAPN5 | c.1050G>T p.R350= (on ENST00000456580; = p.R310= on NM_004055.5) | Silent (SNP) | VAF 31/366 reads (8%) | called by muse, mutect2
- DDI1 | c.1086T>G p.P362= | Silent (SNP) | VAF 34/238 reads (14%) | called by muse, mutect2, varscan2
- EPS8L2 | c.981G>A p.L327= | Silent (SNP) | VAF 12/114 reads (11%) | called by muse, mutect2
- HOXB1 | c.432T>C p.Y144= | Silent (SNP) | VAF 26/242 reads (11%) | called by muse, mutect2, varscan2
- KAT2A | c.987C>T p.T329= | Silent (SNP) | VAF 14/236 reads (6%) | called by muse, mutect2
- KDM3B | c.4821A>G p.K1607= | Silent (SNP) | VAF 36/378 reads (10%) | called by muse, mutect2
- KRT28 | c.624C>T p.T208= | Silent (SNP) | VAF 16/185 reads (9%) | catalogued as rs1432535769; called by muse, mutect2
- KRT75 | c.675G>A p.L225= | Silent (SNP) | VAF 48/712 reads (7%) | called by muse, mutect2
- MARF1 | c.4035A>G p.K1345= | Silent (SNP) | VAF 28/515 reads (5%) | called by muse, mutect2
- MID2 | c.744C>A p.T248= | Silent (SNP) | VAF 18/316 reads (6%) | called by muse, mutect2
- NODAL | c.159G>A p.P53= | Silent (SNP) | VAF 20/335 reads (6%) | catalogued as rs1003188670; called by muse, mutect2
- OOEP | c.297G>T p.R99= | Silent (SNP) | VAF 13/213 reads (6%) | called by muse, mutect2
- PDZD4 | c.1992C>T p.D664= | Silent (SNP) | VAF 26/320 reads (8%) | catalogued as rs371466435; called by muse, mutect2
- PLK3 | c.180C>A p.R60= | Silent (SNP) | VAF 24/213 reads (11%) | called by muse, mutect2, varscan2
- PLXNB1 | c.3672G>T p.T1224= | Silent (SNP) | VAF 18/153 reads (12%) | catalogued as COSV56491352; called by muse, mutect2, varscan2
- RAG1 | c.531T>C p.H177= | Silent (SNP) | VAF 31/523 reads (6%) | called by muse, mutect2
- REV3L | c.4902A>C p.S1634= | Silent (SNP) | VAF 13/217 reads (6%) | called by muse, mutect2
- SLC18A3 | c.408G>T p.L136= | Silent (SNP) | VAF 52/417 reads (12%) | called by muse, mutect2, varscan2
- SLC37A4 | c.117G>T p.V39= | Silent (SNP) | VAF 12/341 reads (4%) | catalogued as COSV58156261; called by muse, mutect2
- TRIO | c.7551G>T p.A2517= | Silent (SNP) | VAF 9/238 reads (4%) | catalogued as rs1325593428; called by muse, mutect2
- TTLL2 | c.1173A>T p.P391= | Silent (SNP) | VAF 32/360 reads (9%) | called by muse, mutect2
- ZCCHC13 | c.291A>G p.L97= | Silent (SNP) | VAF 32/317 reads (10%) | called by muse, mutect2, varscan2
- AC074085.2 | n.185G>T | RNA (SNP) | VAF 30/392 reads (8%) | called by muse, mutect2
- ANKRD42 | chr11:83194414 C>T | 5'Flank (SNP) | VAF 34/274 reads (12%) | catalogued as COSV99473942; called by muse, mutect2, varscan2
- BEAN1 | chr16:66484664 A>T | 3'Flank (SNP) | VAF 37/466 reads (8%) | called by muse, mutect2
- CDIPT | chr16:29864873 G>T | 5'Flank (SNP) | VAF 15/137 reads (11%) | called by muse, mutect2
- CENPN | c.633+122G>A | Intron (SNP) | VAF 14/391 reads (4%) | called by muse, mutect2
- CNOT1 | c.3523-876C>G | Intron (SNP) | VAF 26/236 reads (11%) | catalogued as rs1423406088; called by muse, varscan2
- PDZD7 | chr10:101016379 C>T | 3'Flank (SNP) | VAF 12/298 reads (4%) | catalogued as rs1178980761; called by muse, mutect2
- PIGK | c.987-6936C>T | Intron (SNP) | VAF 18/538 reads (3%) | catalogued as rs1246134956; called by muse, mutect2
- PRSS30P | n.2948C>A | RNA (SNP) | VAF 38/181 reads (21%) | called by muse, mutect2, varscan2
- REG4 | c.*453C>T | 3'UTR (SNP) | VAF 14/213 reads (7%) | catalogued as COSV56653987; called by muse, mutect2
- TPSD1 | chr16:1262919 G>A | 3'Flank (SNP) | VAF 67/252 reads (27%) | catalogued as rs1397493286; called by muse, mutect2, varscan2
- VIM | c.625-38A>G | Intron (SNP) | VAF 10/306 reads (3%) | called by muse, mutect2
- WT1 | chr11:32439306 G>T | 5'Flank (SNP) | VAF 21/222 reads (9%) | called by muse, mutect2
